Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7236, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7236-01A (Primary Tumor).

[page 1 of 4]
DOB:

Sex:

Physician:

Collected:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) RIGHT TONGUE BIOPSY:

Squamous mucosa with skeletal muscle and fibroadipose tissue, no tumor present.

(B) LEFT TONGUE BIOPSY:

INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED.

(C) LEFT PARTIAL GLOSSECTOMY:

INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED, 3.0 CM.

DEPTH OF INVASION 1.0 CM.

PERINEURAL INVASION PRESENT FOCALLY.

(D) LEFT BUCCAL MUCOSAL MARGIN:

Squamous mucosa and skeletal muscle, no tumor present.

(E) RETROMOLAR TRIGONE, LEFT:

Squamous mucosa and minor salivary gland, no tumor present.

(F) TONGUE, MUCOSAL MARGIN ANTERIOR:

Squamous mucosa, minor salivary gland and skeletal muscle, no tumor present.

(G) TONGUE BASE:

Squamous mucosa with lymphoid stroma and minor salivary glands, no tumor present.

(H) VENTRAL TONGUE, ANTERIOR MARGIN:

Squamous mucosa and skeletal muscle, no tumor present.

(I) VENTRAL TONGUE, MEDIAL MARGIN:

Squamous mucosa and skeletal muscle, no tumor present.

(J) ANTERIOR GINGIVAL MARGIN:

Squamous mucosa with inflammation, no tumor present.

(K) LATERAL GINGIVAL MARGIN:

Squamous mucosa with inflammation, no tumor present.

(L) RIGHT NECK DISSECTION, LEVEL I "A":

Four lymph nodes, no tumor present (0/4).

(M) RIGHT NECK DISSECTION, LEVEL I "B":

METASTATIC SQUAMOUS CARCINOMA IN ONE OF ONE LYMPH NODE (1/1).

Extranodal extension not identified.

Salivary gland, no tumor present.

(N) RIGHT NECK DISSECTION, LEVEL II:

Thirteen lymph nodes, no tumor present (0/13).

(O) RIGHT NECK DISSECTION, LEVELS III AND IV:

METASTATIC SQUAMOUS CARCINOMA IN ONE OF THIRTEEN LYMPH NODES (1/13).

Extranodal extension not identified.

(P) LEFT NECK DISSECTION LEVEL I "B":

METASTATIC SQUAMOUS CARCINOMA IN ONE OF TWO LYMPH NODES WITH EXTRANODAL EXTENSION (1/2).

(Q) LEFT NECK DISSECTION LEVEL II "A":

METASTATIC SQUAMOUS CARCINOMA IN TWO OF EIGHT LYMPH NODES (2/8).

Extranodal extension not identified.

[page 2 of 4]
- (R) LEFT NECK DISSECTION LEVEL II "B":
METASTATIC SQUAMOUS CARCINOMA IN TWO OF TWO LYMPH NODES (2/2).
Extranodal extension not identified.
- (S) LEFT NECK DISSECTION LEVELS III AND IV:
Four lymph nodes, no tumor present (0/4).

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

- (A) RIGHT TONGUE BIOPSY - A pink-red fragment of soft tissue measuring 0.5 x 0.4 cm. The specimen is bisected. One-half is submitted to research and the other half is processed for routine histology in cassette A. [REDACTED]
- (B) LEFT TONGUE BIOPSY - A punch of a tan, soft tissue measuring 0.5 x 0.3 x 0.3 cm. Tissue is bisected. One-half is submitted for research and the other half is submitted for routine histology in cassette B. [REDACTED]
- (C) LEFT PARTIAL GLOSSECTOMY - A partial glossectomy 5.0 x 4.0 x 2.5 cm. In the center of the specimen, there is a necrotic ulcerated mass, 3.0 x 2.3 x 1.0 cm, with the maximum depth of invasion grossly 1.0 cm. The specimen is serially sectioned from anterior to posterior and submitted in twelve cassettes. Tissue given to tumor bank. [REDACTED]
- (D) LEFT BUCCAL MUCOSAL MARGIN - A 3.7 x 0.5 x 0.3 cm piece of pink-tan mucosal lined tissue. The specimen is bisected and submitted entirely for frozen section diagnosis. [REDACTED]
*FS/DX: NEGATIVE FOR TUMOR. [REDACTED]
- (E) RETROMOLAR TRIGONE LEFT - Two fragments of pink-tan mucosal lined tissue measuring 0.7 and 1.2 cm in maximum dimension each. The specimen is submitted entirely for frozen section. [REDACTED]
*FS/DX: NEGATIVE FOR TUMOR. [REDACTED]
- (F) TONGUE, MUCOSAL MARGIN ANTERIOR TWO-THIRDS - A 7.0 x 0.6 x 0.4 cm piece of pink-tan mucosa lined tissue. The specimen is serially sectioned and submitted entirely for frozen section diagnosis.
SECTION CODE: F1, F2, tongue mucosal margin, entirely submitted for frozen section. [REDACTED]
*FS/DX: NEGATIVE FOR TUMOR. [REDACTED]
- (G) TONGUE BASE - A 2.0 x 0.6 x 0.6 cm piece of pink-tan mucosal lined tissue. The specimen is submitted entirely for frozen section diagnosis. [REDACTED]
*FS/DX: NEGATIVE FOR TUMOR. [REDACTED]
- (H) VENTRAL TONGUE, ANTERIOR MARGIN - A 1.1 x 0.7 x 0.3 cm piece of soft red-tan tissue. The specimen is submitted entirely for frozen section diagnosis. [REDACTED]
*FS/DX: NEGATIVE FOR TUMOR. [REDACTED]
- (I) VENTRAL TONGUE, MEDIAL MARGIN - Two pieces of pink-tan mucosal lined tissue measuring 1.0 and 1.5 cm in maximum dimension each. The specimen is submitted entirely for frozen section diagnosis. [REDACTED]
*FS/DX: FOCAL DYSPLASIA, CAUTERY AND TANGENTIAL SECTIONING PRECLUDES GRADING OF DYSPLASIA.
[REDACTED]

[page 3 of 4]
(J) ANTERIOR GINGIVAL MARGIN - Two pieces of pink-tan mucosal lined tissue measuring 0.4 and 0.6 cm in maximum dimension each. The specimen is submitted entirely for frozen section diagnosis. [REDACTED]

*FS/DX: NEGATIVE FOR TUMOR. [REDACTED]

(K) LATERAL GINGIVAL MARGIN - A 1.0 x 0.3 x 0.2 cm piece of pink-tan mucosal lined tissue. The specimen is submitted entirely for frozen section diagnosis. [REDACTED]

*FS/DX: NEGATIVE FOR TUMOR. [REDACTED]

(L) RIGHT NECK DISSECTION, LEVEL I "A" - A 5.0 x 2.5 x 1.0 cm portion of lymph node bearing fibroadipose tissue. Four possible lymph nodes are identified ranging from 0.2 to 0.4 cm.

SECTION CODE: L, four possible lymph nodes, intact. [REDACTED]

(M) LEVEL I "B" NECK DISSECTION RIGHT - A 4.5 x 3.5 x 1.8 cm portion of lymph node bearing fibroadipose tissue within which there is a 4.0 x 2.2 x 2.0 cm unremarkable parotid and a single 1.0 x 0.8 x 0.6 cm lymph node.

SECTION CODE: M1, representative section of parotid gland; M2, one possible lymph node, bisected. [REDACTED]

(N) LEVEL II NECK DISSECTION RIGHT - A 4.0 x 2.5 x 1.1 cm portion of lymph node bearing fibroadipose tissue. Thirteen possible lymph nodes are identified ranging from 0.5 up to 1.2 cm in maximum dimension.

SECTION CODE: N1, five possible lymph nodes, intact; N2, four possible lymph nodes, intact; N3, one possible lymph node, bisected; N4, three possible lymph node, intact. [REDACTED]

(O) LEVELS III AND IV NECK DISSECTION, RIGHT - A 7.0 x 3.0 x 1.5 cm portion of lymph node bearing fibroadipose tissue. Thirteen possible lymph nodes are identified ranging from 0.2 up to 1.5 cm in maximum dimension.

SECTION CODE: O1, five possible lymph nodes, intact; O2, four possible lymph nodes, intact; O3, three possible lymph nodes, intact; O4, one possible lymph node, bisected. [REDACTED]

(P) LEFT NECK DISSECTION LEVEL I "B" - A salivary gland (3.5 x 2.5 x 1.2 cm) and fibroadipose tissue (2.5 x 1.5 x 1.5 cm). The specimen is serially sectioned. Cut surface displays unremarkable salivary gland. Two lymph nodes (0.8 x 0.6 x 0.6 cm and 1.2 x 1.2 x 1.0 cm) are identified.

SECTION CODE: P1, representative section of salivary gland; P2, one lymph node, trisected; P3, one lymph node, serially sectioned. [REDACTED]

(Q) LEFT NECK DISSECTION LEVEL II "A" - Fibroadipose tissue (6.0 x 3.0 x 1.5 cm). Eight lymph nodes are identified ranging from 0.2 x 0.2 x 0.2 to 2.2 x 1.2 x 1.0 cm.

SECTION CODE: Q1, six lymph nodes; Q2, one lymph node, serially sectioned; Q3, Q4, one lymph node, serially sectioned. [REDACTED]

(R) LEFT NECK DISSECTION LEVEL II "B" - Fibroadipose tissue (4.0 x 2.5 x 1.5 cm). Two lymph nodes (0.5 x 0.4 x 0.4 and 2.2 x 1.5 x 1.2 cm) are identified.

SECTION CODE: R1, one lymph node, bisected; R2, R3, representative section of one grossly positive lymph node.

PX/msm

(S) LEFT NECK DISSECTION LEVELS III AND IV - Fibroadipose tissue (4.0 x 2.0 x 1.5 cm). Four possible lymph nodes are identified ranging from 0.3 x 0.3 x 0.3 cm to 0.7 x 0.4 x 0.4 cm.

SECTION CODE: S1, two lymph nodes; S2, two possible lymph nodes. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-53000, M-80703

[page 4 of 4]
Released by

Source: NCI Genomic Data Commons file 4c3889dc-e311-40ca-923e-8e50f02dff82 (TCGA-CV-7236.1E7A5C08-E062-47A9-B518-D3E9BFF82729.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).